CPTAC case C3L-06418 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/616558b0-b21d-472b-a246-dedec4c01079

Demographics
Sex at birth: male; Race: white; Year of birth: 1951; Vital status: Alive; Country of birth: Ukraine.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Fundus of stomach; Age at diagnosis: 68.4 years (24,990 days); Year of diagnosis: 2019; AJCC staging edition: 8th; AJCC pathologic T: T4a; AJCC pathologic N: N1; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Residual disease: R0; Days to last known disease status: 1,109 days (3.0 years); Days to last follow up: 1,109 days (3.0 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 5 cm; Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 7.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Days to treatment start: 45 days; Days to treatment end: 48 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Days to treatment start: 45 days; Days to treatment end: 48 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 107 days; Days to treatment end: 112 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 107 days; Days to treatment end: 112 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Days to treatment start: 135 days; Days to treatment end: 141 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Days to treatment start: 135 days; Days to treatment end: 141 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 165 days; Days to treatment end: 169 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 165 days; Days to treatment end: 169 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Leucovorin; Days to treatment start: 237 days; Days to treatment end: 241 days; Treatment outcome: Stable Disease.

Follow-up (3 entries)
- Days to follow up: 376 days (1.0 years); Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 2.
- Days to follow up: 741 days (2.0 years); Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 2.
- Follow-up contact recording only the day: day 1,109.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-06418-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Fundus Of Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 10 days; Initial weight: 630 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-06418-21: Section location: Fundus; Percent tumor nuclei: 60; Percent necrosis: 0.
- Sample C3L-06418-05: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Fundus Of Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 10 days; Initial weight: 500 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-06418-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 10 days; Method of sample procurement: Blood Draw.
